HCMI case HCM-WCMC-0494-C16 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/858a84e1-002b-451c-a2dc-cf5673f08992

Demographics
Sex at birth: male; Race: asian; Year of birth: 1952; Vital status: Alive.

Diagnoses (1)
1. Mucinous adenocarcinoma: ICD-O-3 morphology code: 8480/3; ICD-10 code: C16.9; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Body of stomach; Classification of tumor: primary; Age at diagnosis: 64.9 years (23,717 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IIA; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Pathology details: Additional pathology findings: Intestinal metaplasia.
   Pathology details: Additional pathology findings: Autoimmune atrophic chronic gastritis.
   Pathology details: Lymphatic invasion present: No; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 44 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 95 days; Days to treatment end: 190 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 121 days; Days to treatment end: 149 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 121 days; Days to treatment end: 155 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 1,585 days (4.3 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 762.

Molecular and laboratory tests
- ERBB2 (IHC): Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 59.9 kg.
- Timepoint category: Prior to Diagnosis; Risk factors: Intestinal Metaplasia / Autoimmune Atrophic Chronic Gastritis.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (2 samples)
- Sample HCM-WCMC-0494-C16-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-WCMC-0494-C16-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 14.
